Somatic mutation profile of tumor specimen TCGA-BK-A139-01A (aliquot TCGA-BK-A139-01A-11D-A122-09) from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b1e5e31-8536-4b64-8b54-bb014ce3b995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A139-10A (Blood Derived Normal), aliquot TCGA-BK-A139-10A-01D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ac11d4c-db7f-48e0-99cc-be5ed9b32a3a

The open-access MAF lists 138 somatic variants for this specimen: 105 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 29, Nonsense Mutation 3, Splice Region 2, Splice Site 1, Intron 1, Frame Shift Del 1, In Frame Del 1, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1717_1722del p.L573_R574del (on ENST00000521381 / NM_181523.3; = p.L303_R304del on NM_181504.4) | In Frame Del (DEL) | VAF 136/321 reads (42%) | hotspot (GDC flag); catalogued as COSV57129439; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 114/211 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99716360; called by muse, mutect2, varscan2
- ANK3 | c.8476T>A p.S2826T | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99779249; called by muse, mutect2
- ANKRD17 | c.4488A>T p.R1496S | Missense Mutation (SNP) | VAF 60/833 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV100428552; called by muse, mutect2
- ANKRD17 | c.4487G>T p.R1496I | Missense Mutation (SNP) | VAF 60/828 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV100428554; called by muse, mutect2
- ARFGEF2 | c.3900C>G p.Y1300* | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as COSV100904175; called by muse, mutect2
- ASGR2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs775565123, COSV54690086; called by muse, mutect2, varscan2
- ASH2L | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 156/355 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51698421; called by muse, mutect2, varscan2
- ATP7A | c.2551G>A p.V851I | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100431849; called by muse, mutect2
- AXDND1 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs1328041323, COSV62642011; called by muse, mutect2, varscan2
- BCL7A | c.233C>G p.P78R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99946903; called by muse, mutect2
- BRCA2 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs80358517, COSV66452882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.4183C>T p.R1395* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99607231; called by muse, mutect2
- CAMKV | c.637C>T p.L213= | Splice Region (SNP) | VAF 39/157 reads (25%) | catalogued as rs200019805, COSV56555122; called by muse, mutect2, varscan2
- CAPRIN1 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs759068488, COSV58219562; called by muse, mutect2, varscan2
- CBX6 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53320749; called by muse, mutect2, varscan2
- CCDC82 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182611261, COSV53593198; called by muse, mutect2, varscan2
- CDADC1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51911319; called by muse, mutect2, varscan2
- CDH7 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59885250; called by muse, mutect2, varscan2
- COL9A2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.912); catalogued as rs199850925, COSV65622693; called by muse, varscan2
- CPNE8 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1404165216, COSV58842313, COSV58848917; called by muse, mutect2, varscan2
- DMXL2 | c.3188G>C p.S1063T | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51845230; called by muse, mutect2, varscan2
- DNAJC1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100977997; called by muse, mutect2
- DOCK7 | c.4833T>A p.F1611L (on ENST00000635253 / NM_001367561.1; = p.F1580L on NM_033407.3) | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52003612; called by muse, mutect2, varscan2
- DSC2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV51864126; called by muse, mutect2, varscan2
- DTL | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1290740031; called by muse, mutect2
- DYNLRB1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs573896721, COSV64063820; called by muse, varscan2
- ECD | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65901392; called by muse, mutect2
- ELF5 | c.212A>T p.E71V (on ENST00000312319 / NM_198381.2; = p.E61V on NM_001422.4) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56628736; called by muse, mutect2, varscan2
- ELMO1 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV60295487; called by muse, mutect2
- EVC2 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs776531365, COSV60388298; called by muse, mutect2, varscan2
- FAM151B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 181/301 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56472878; called by muse, mutect2, varscan2
- FAT1 | c.6488C>A p.A2163D | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV71673152, COSV71673571; called by muse, mutect2, varscan2
- FAT3 | c.4670A>G p.E1557G | Missense Mutation (SNP) | VAF 80/457 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99961793; called by muse, mutect2, varscan2
- FETUB | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 82/651 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54005465; called by muse, varscan2
- FOXF2 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs181428616, COSV52525311; called by muse, mutect2, varscan2
- FOXR1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs150635174, COSV57652017; called by muse, mutect2, varscan2
- GLI3 | c.4628C>G p.A1543G | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.701); catalogued as COSV67887890, COSV67895815; called by muse, mutect2, varscan2
- GSAP | c.2294G>T p.R765I | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1201603617, COSV57529582; called by muse, mutect2, varscan2
- GSDME | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61651528; called by muse, mutect2, varscan2
- H3-3A | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV64732596; called by muse, mutect2, varscan2
- HELT | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58819880; called by muse, mutect2, varscan2
- HLA-DQA2 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV100890695; called by muse, mutect2
- IVL | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100908140; called by muse, mutect2
- KCNH8 | c.1806C>G p.S602R | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV100109272; called by muse, mutect2
- KCNN1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs1260374056, COSV55838552; called by muse, mutect2, varscan2
- KCTD17 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63248902; called by muse, mutect2, varscan2
- KDM3B | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1561770083, COSV58690112; called by muse, mutect2, varscan2
- KIT | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as COSV55395364; called by muse, mutect2
- LACTB | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1314145412, COSV56055541; called by muse, mutect2
- LCE2B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs767189385, COSV64227613; called by muse, mutect2, varscan2
- LGI4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs144343503, COSV100032601; called by muse, mutect2, varscan2
- LONP2 | c.1464A>G p.I488M | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53522139; called by muse, mutect2, varscan2
- MKNK2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.491); catalogued as COSV51732110; called by muse, mutect2, varscan2
- MTMR10 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 36/163 reads (22%) | catalogued as COSV58727977; called by muse, mutect2, varscan2
- MTMR8 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV66393605; called by muse, mutect2, varscan2
- MUC17 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 261/545 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV60287027; called by muse, mutect2, varscan2
- MYO1H | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764150151, COSV60443340; called by muse, mutect2, varscan2
- NRG1 | c.1451C>A p.P484Q (on ENST00000405005 / NM_013964.5; = p.P489Q on NM_013956.5) | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55157105; called by muse, mutect2, varscan2
- OCIAD1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51900609; called by muse, mutect2, varscan2
- OR2B11 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 55/459 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV59510030; called by muse, mutect2, varscan2
- OR51E2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs151286283; called by muse, mutect2, varscan2
- OR8K1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 108/349 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54402287, COSV54403778; called by muse, mutect2, varscan2
- OSMR | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 143/636 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV57084303; called by muse, varscan2
- PCLO | c.9754A>G p.M3252V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1181678596, COSV100430120; called by muse, mutect2
- PCNX4 | c.2882T>C p.I961T (on ENST00000406854 / NM_001330177.2; = p.I727T on NM_022495.5) | Missense Mutation (SNP) | VAF 131/293 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58303752; called by muse, mutect2, varscan2
- PLXND1 | c.4412T>C p.I1471T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1389101617, COSV100139403; called by muse, mutect2, varscan2
- PRDM14 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV52571980; called by muse, mutect2, varscan2
- PSME4 | c.4705C>A p.Q1569K | Missense Mutation (SNP) | VAF 96/557 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV66363135, COSV66364667; called by muse, mutect2, varscan2
- PSME4 | c.4222C>A p.L1408M | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101122402; called by muse, mutect2
- PTCH1 | c.3070C>A p.L1024I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100107462; called by muse, varscan2
- PTPRN2 | c.318C>A p.D106E | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101233607; called by muse, mutect2
- SIGLEC8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs746803267, COSV100367206, COSV58471655; called by muse, mutect2, varscan2
- SLC20A2 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); catalogued as rs1055093172, COSV60603252, COSV60607612; called by muse, mutect2, varscan2
- SLC44A5 | c.1624+2T>A p.X542_splice | Splice Site (SNP) | VAF 32/223 reads (14%) | catalogued as COSV63763600; called by muse, mutect2, varscan2
- SMR3A | c.45del p.C16Vfs*106 | Frame Shift Del (DEL) | VAF 146/954 reads (15%) | catalogued as COSV56949617, COSV56950143; called by pindel, varscan2
- SPIN3 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100888463; called by muse, mutect2, varscan2
- TECTA | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV50703368; called by muse, mutect2, varscan2
- TENM3 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV69306268; called by muse, mutect2, varscan2
- TLL1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 133/541 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50275636, COSV50308643; called by muse, mutect2, varscan2
- TMC7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58583118; called by muse, mutect2, varscan2
- TMEM47 | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327464; called by muse, varscan2
- TNIK | c.3380C>A p.P1127Q | Missense Mutation (SNP) | VAF 27/841 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99456308; called by muse, mutect2
- TRIM67 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs372382212, COSV64158042; called by muse, mutect2, varscan2
- TRIM69 | c.834T>C p.H278= (on ENST00000329464 / NM_182985.5; = p.H119= on NM_080745.5) | Splice Region (SNP) | VAF 118/339 reads (35%) | catalogued as rs1264818442, COSV57803580; called by muse, mutect2, varscan2
- TTC17 | c.190C>G p.H64D | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV50008171; called by muse, mutect2, varscan2
- VCAN | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV54103886; called by muse, mutect2, varscan2
- XIRP2 | c.7142A>C p.E2381A (on ENST00000628543; = p.E2556A on NM_152381.6) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54696516; called by muse, mutect2, varscan2
- ZBTB24 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs761960881, COSV57781908; called by muse, mutect2, varscan2
- ZBTB38 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58541374; called by muse, mutect2, varscan2
- ZFHX4 | c.5653A>T p.T1885S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99260694; called by muse, mutect2
- ZNF222 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 50/792 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756334418, COSV99496215; called by muse, mutect2
- ZNF254 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 87/434 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV60054126; called by muse, mutect2, varscan2
- ZNF786 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV60275865; called by muse, mutect2, varscan2
- ZNF91 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.195); catalogued as rs1449451716, COSV100322494; called by muse, mutect2
- ASH1L | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); called by muse, mutect2
- CTNNBL1 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- FN1 | c.4076A>T p.D1359V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2
- FOXP2 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FRMPD2 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2
- GABRA4 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAREM1 | c.2443G>A p.E815K (on ENST00000269209 / NM_001242409.2; = p.E814K on NM_022751.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MUC16 | c.2018C>A p.T673K | Missense Mutation (SNP) | VAF 6/184 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SYNE1 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA4 | c.1953G>T p.L651= | Silent (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 39/332 reads (12%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- ARHGEF5 | c.4602C>T p.A1534= | Silent (SNP) | VAF 39/241 reads (16%) | catalogued as rs1040382186, COSV50209723; called by muse, mutect2, varscan2
- CACNB2 | c.858A>G p.L286= (on ENST00000324631 / NM_201596.3; = p.L231= on NM_000724.4) | Silent (SNP) | VAF 56/219 reads (26%) | catalogued as COSV56621483; called by muse, mutect2, varscan2
- CNTNAP2 | c.1767C>A p.T589= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV62209136; called by muse, mutect2
- COL6A1 | c.357G>A p.A119= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs747037863, COSV62612876, COSV62614791; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DDX24 | c.1680G>A p.V560= | Silent (SNP) | VAF 172/392 reads (44%) | catalogued as rs767350697, COSV58212349; called by muse, mutect2, varscan2
- DHRS7C | c.840C>T p.P280= (on ENST00000330255 / NM_001220493.2; = p.P279= on NM_001105571.3) | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV57650551; called by muse, mutect2, varscan2
- DNM2 | c.1143G>A p.E381= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as COSV58960896; called by muse, mutect2, varscan2
- DOCK3 | c.1861C>A p.R621= | Silent (SNP) | VAF 30/364 reads (8%) | catalogued as rs369862076, COSV56544794, COSV99810601; called by muse, mutect2
- FLT3 | c.2448C>T p.N816= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs369177963; ClinVar: likely benign; called by muse, mutect2
- GCLM | c.753G>A p.S251= | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as rs567112849, COSV64686989; called by muse, mutect2, varscan2
- KPTN | c.640C>A p.R214= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV57645017; called by muse, mutect2, varscan2
- LAMA2 | c.5937C>T p.N1979= | Silent (SNP) | VAF 50/426 reads (12%) | catalogued as rs747714599, COSV70345709; called by muse, mutect2, varscan2
- MLIP | c.333C>T p.F111= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as rs201706379; called by muse, mutect2, varscan2
- MORC1 | c.1806T>C p.D602= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV51735029; called by muse, mutect2
- PAPPA | c.3480G>A p.Q1160= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV60282159; called by muse, mutect2, varscan2
- PSPC1 | c.504C>T p.S168= | Silent (SNP) | VAF 83/182 reads (46%) | catalogued as COSV58887893; called by muse, mutect2, varscan2
- PTCRA | c.225C>T p.T75= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as rs1288816535, COSV100485726; called by muse, mutect2
- SCN5A | c.1380C>T p.S460= | Silent (SNP) | VAF 143/362 reads (40%) | catalogued as COSV61122478; called by muse, mutect2, varscan2
- SLC24A2 | c.978G>A p.P326= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as rs200713923; called by muse, mutect2
- SOWAHB | c.111C>G p.P37= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV57554295, COSV57554402; called by muse, mutect2, varscan2
- ST8SIA1 | c.306G>A p.G102= | Silent (SNP) | VAF 18/339 reads (5%) | called by muse, mutect2
- SUZ12 | c.546T>C p.V182= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV59499700; called by muse, mutect2, varscan2
- TCF3 | c.474G>C p.R158= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs755980732, COSV99513550; called by muse, mutect2
- TEKT2 | c.912G>T p.L304= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV52880871; called by muse, mutect2, varscan2
- TTL | c.123G>A p.L41= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV51974322; called by muse, mutect2, varscan2
- VIL1 | c.627C>T p.G209= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs767787005, COSV50287346; called by muse, mutect2, varscan2
- ZFC3H1 | c.1762T>C p.L588= | Silent (SNP) | VAF 107/334 reads (32%) | catalogued as COSV66432066; called by muse, mutect2, varscan2
- CACNB4 | c.148-90332T>C | Intron (SNP) | VAF 36/362 reads (10%) | catalogued as COSV99137960; called by muse, mutect2
- MTRNR2L6 | chr7:142671057 T>A | 3'Flank (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- SSPOP | n.5698G>A | RNA (SNP) | VAF 4/15 reads (27%) | catalogued as rs766327797, COSV50487245; called by muse, mutect2
- TSPAN6 | c.-1C>T | 5'UTR (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100885744; called by muse, mutect2, varscan2
